MMRF case MMRF_1389 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a607741b-0df0-43ad-8c60-79e6d7b45a94

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.9 years (18,960 days); ISS stage: I; Days to last known disease status: 715 days (2.0 years); Days to last follow up: 715 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 78 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 183 days; Days to treatment end: 183 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 183 days; Days to treatment end: 183 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.665 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 136 mg/dL; Immunoglobulin G 5.22 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 3.16 µg/mL; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 5.12 mmol/L; C-Reactive Protein 0.15 mg/dL.
- Day 92: Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.725 mg/dL; Immunoglobulin G 5.42 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.33 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 4.9 mmol/L.
- Day 225 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 9.31 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 6.16 mmol/L.
- Day 351 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 4.35 mmol/L.
- Day 540 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.754 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.95 µg/mL; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 6.05 mmol/L.
- Day 631 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.658 mg/dL; Immunoglobulin G 8.82 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 4.35 mmol/L.
- Day 715 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 4.79 mmol/L.

Other clinical attributes
- Day -17: Weight: 74 kg; Height: 164 cm.

Biospecimens (4 samples)
- Sample MMRF_1389_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_1389_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
- Sample MMRF_1389_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 351 days.
- Sample MMRF_1389_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 351 days.
